TCGA case TCGA-EY-A1G7 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6b2e93b9-8271-4205-842e-0b7292b8115a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 86 years; Vital status: Dead; Days to death: 189 days.

Diagnoses (3)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 86.5 years (31,603 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; FIGO stage: Stage II; FIGO staging edition year: 1988; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes tested: 0.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 96.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 99 days; Days to treatment end: 99 days; Treatment dose: 500 cGy; Course number: 1; Number of fractions: 2; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Implants; Treatment intent type: Palliative; Days to treatment start: 102 days; Days to treatment end: 124 days; Treatment dose: 1,050 cGy; Course number: 2; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Uterus, NOS; Classification of tumor: Prior primary; FIGO stage: Stage I; FIGO staging edition year: 1995.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -647 days (-1.8 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.
3. Diagnosis record without a diagnosis name: Age at diagnosis: 86.8 years (31,698 days); Days to diagnosis: 95 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 95 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 189 days; Disease response: With Tumor.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 4+; Pregnancy outcome: Full Term Birth, NOS.
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 151 cm; BMI: 37.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EY-A1G7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 140 mg.
  Slide TCGA-EY-A1G7-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 20.
- Sample TCGA-EY-A1G7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EY-A1G7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Tumor resection; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Partial Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Uterus; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -686.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: Yes.

GDC annotations on this case (curator notes; quoted as recorded):
- Case submitted is found to be a recurrence after submission: patient had a prior endometrial maligancy.
- History of unacceptable prior treatment related to a prior/other malignancy: Patient had a previous uterine adenocarcinoma of the uterus treated with locoregional radiation. No systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 189 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 189 days; disease-free interval: event (new tumor event after initially disease-free), 95 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 95 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-EY-A1G7-01): tumor purity 0.92, ploidy 2.26, whole-genome doublings 0 (call status: legacy_call).
